CPTAC case C3L-00606 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/12246e82-cb5f-4b7e-a6bd-a120e000db49

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Dead; Days to death: 1,045 days (2.9 years); Year of death: 2019; Cause of death: Cancer Related.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 75.7 years (27,636 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,045 days (2.9 years); Progression or recurrence: yes; Days to last follow up: 1,045 days (2.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm (a second GDC size field records 1.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 5; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (4 entries)
- Days to follow up: 269 days; Disease response: Tumor Free.
- Days to follow up: 673 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,045 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,045 days (2.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 780 days (2.1 years).

Other clinical attributes
- Weight: 105 kg; Height: 157.5 cm; BMI: 42.33; Comorbidities: Hypertension.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 15; Cigarettes per day: 30; Tobacco smoking onset year: 1966; Tobacco smoking quit year: 1976; Exposure duration years: 10.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00606-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 438 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00606-21: Section location: Middle; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-00606-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 374 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00606-22: Section location: Middle; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3L-00606-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 387 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00606-23: Section location: Middle; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-00606-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 349 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00606-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
